Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3B7, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3B7-01A (Primary Tumor).

[page 1 of 3]
Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- A. Right ureter distal margin; excision:
- Portion of ureter, no tumor.

- B. Left distal ureter; excision:
- Portion of ureter, no tumor.

- C. Left pelvic lymph nodes; dissection:
- Nine lymph nodes, no tumor (0/9).

- D. Right pelvic lymph nodes; dissection:
- Seven lymph nodes, no tumor (0/7).

- E. Left ureter; excision:
- Portion of ureter, no tumor.

- F. Urinary bladder, prostate and seminal vesicles; cystoprostatectomy:
- Invasive high grade urothelial carcinoma of the bladder, with markedly pleomorphic and poorly differentiated areas, see pathologic parameters.
- Incidental adenocarcinoma of the prostate, see pathologic parameters.

- G. Right ureter; excision:
- Portion of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

- Tumor type: Invasive urothelial carcinoma.
- Grade of tumor: High grade, with markedly pleomorphic and poorly differentiated areas.
- Depth of invasion: Extravesicular soft tissue (microscopic).
- Tumor distribution: Solitary, 6.0 cm, at right lateral and anterior walls.
- Ureteral margins: Negative for tumor.
- Distal urethral margin: Negative for tumor.
- Soft tissue margin or serosa: Negative for tumor.
- Lymph nodes: Negative for tumor (0/16).
- pTNM: pT3a,N0,MX.

Effective : this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

- Gleason Score: 3+3=6.
- Perineural Invasion: Absent.
- Tumor Location: Peripheral zone - right.
- Tumor Volume Estimate: <2%.
- High-grade P.I.N.: Multifocal.
- Seminal Vesicles: Negative for tumor.
- Extraprostatic extension: Absent.
- Peripheral Margin: Negative for tumor.
- Distal (apical) Margin: Negative for tumor.
- Proximal (basilar) Margin: Negative for tumor.
- Regional Lymph Nodes (right and left): Negative for tumor (0/16).

1CD-0-3

carcinoma, urothelial, nos 8/20/3

Path - site: bladder, wall nos C67.9

CQCF: bladder, wall, lateral C67.2

hw

10/21/11

[page 2 of 3]
12. pTNM: pT2a,N0,MX.

Effective this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

XX

[], MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D.

Electronically Signed Out by [], MD

Clinical History:
Bladder Cancer

Specimens Received:

A: Right ureter distal margin

B: Left distal ureter

C: Left pelvic lymph nodes

D: Right pelvic lymph nodes

E: Left ureter

F: Bladder, prostate & seminal vesicles

G: Right ureter

Gross Description:

The specimens are received in seven containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right ureter distal margin". Received fresh and placed in formalin is a unoriented 0.9 cm length of ureter with a diameter of 0.4 cm and a lumen of less than 0.1 cm. Specimen is serially sectioned and submitted between sponges in cassette A1.

B. The second container is additionally identified as, "left distal ureter". Received fresh and placed in formalin is a unoriented 0.1 cm length of probable ureter with a diameter of 0.4 cm and a lumen of less than 0.1 cm. Specimen is submitted between sponges in cassette B1.

C. The third container is additionally identified as, "left pelvic lymph nodes". Received fresh and placed in formalin is a 4.5 x 3.5 x 2.0 cm aggregate of fibrofatty tissue which is dissected to reveal multiple types of lymph nodes ranging in size from 0.5-2.2 cm. Specimen is entirely submitted as follows

C1 one lymph node bisected

C2 one lymph node bisected

C3 one lymph node bisected

C4 one lymph node bisected

C5 4 nodes

C6 adjacent fibrous tissue

D. The fourth container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin is a 5 x 4 x 3 cm aggregate of fibrofatty tissue which is dissected to reveal multiple types of lymph nodes ranging in size from 0.5-3 cm. Specimen is entirely submitted as follows

D1-2 one lymph node bisected

D3-4 one lymph node bisected

D5 4 nodes

D6 3 nodes

E. The fifth container is additionally identified as, "left ureter". Received fresh and placed in formalin is 2.4 cm length of ureter with a diameter of 0.4 cm and a lumen of less than 0.1 cm with a small amount of attached fibrous

[page 3 of 3]
tissue. There is a plastic clip and stitch at one end. This end is inked black. The ureter is serially sectioned and submitted between sponges in cassette E1-2.

F. The sixth container is additionally identified as, "bladder, prostate and seminal vesicles". Received fresh and placed in formalin is a 403 g, 14 x 11 x 3 cm cystoprostatectomy specimen consisting of a bladder which measures 12x11x3.5 cm. The right ureteral stump measures 2 cm and the left 2.4 cm, and both demonstrate patent lumina. The prostate measures 4.8 x 4 x 4 cm. The right seminal vesicle measures 3.5 x 1.5 cm and the right vas deferens 6 cm. The left seminal vesicle measures 3 x 1.5 cm and the left vas deferens 8 cm. The right half of the prostate and bladder is inked blue and the left half is inked black. The prostate is opened anteriorly along the urethra and continued superiorly through the bladder in a Y-shaped incision. The prostate is serially sectioned from apex to base to reveal unremarkable parenchyma. The bladder demonstrates an exophytic hemorrhagic yellow-tan 6 x 5.5 cm mass involving the anterior and right wall. Serial sectioning reveals tumor invasion to a depth of 1.8 cm, extending to 0.2 cm of the inked margin. There is a 4.5 x 4 cm diverticulum which shaggy red mucosa involving the posterior left aspect of the bladder. The remainder of the mucosa is tan-brown, edematous, and glistening with a uniform 0.4 cm wall thickness. The bilateral ureteral orifices are identified and probe patent. The tumor extends to within 0.1 cm of the right ureteral orifice

Gross photographs are taken.

Representative sections are submitted as follows:

- F1: Distal urethral margin
- F2: Prostatic apical margin
- F3: Right ureteral margin
- F4: Left ureteral margin
- F5-8: Representative prostate through verumontanum
- F9-12: Representative prostate above verumontanum
- F13: Seminal vesicles and vasa deferentia
- F14: Right ureteral orifice
- F15: Left ureteral orifice
- F16-22: Multiple tumor sections
- F23-24: Diverticulum
- F25: Uninvolved dome
- F26: Uninvolved anterior wall
- F27: Uninvolved posterior wall
- F28: Uninvolved right wall
- F29: Uninvolved left wall
- F30: Uninvolved trigone

G. The seventh container is additionally identified as, "right ureter". Received fresh and placed in formalin is 2.4 cm length of ureter with a diameter of 0.4 cm and a lumen of less than 0.1 cm with a small amount of attached fibrous tissue. There is a plastic clip and stitch at one end. This end is inked black. The ureter is serially sectioned and submitted between sponges in cassette G1-2.

xxx
[] M.D.

Source: NCI Genomic Data Commons file 1684dad9-547e-4953-93ec-c6eac38e9cbc (TCGA-FD-A3B7.DC81B464-642D-444E-A110-D11E687B36C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).